Somatic mutation profile of tumor specimen MP2PRT-PAVNTA-TMP1-A (aliquot MP2PRT-PAVNTA-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVNTA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (770 days).
Specimen MP2PRT-PAVNTA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de9bb320-9ede-4fc3-a4ba-0383a793fd2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVNTA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVNTA-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd61116d-4a24-4f4a-8081-ba56085bb8b5

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR1P1 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 55/398 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs1255704638; called by muse, mutect2, varscan2
- PLXNB1 | c.4609C>T p.R1537W | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs866211567, COSV56491913; called by muse, mutect2, varscan2
- PRKG1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 92/321 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64816672; called by muse, mutect2, varscan2
- STOX2 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 114/405 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1192479663, COSV100408204, COSV57851546; called by muse, mutect2, varscan2
- OR13C9 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 120/317 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- GREB1L | c.3126T>A p.P1042= | Silent (SNP) | VAF 32/217 reads (15%) | called by muse, mutect2, varscan2
- IGFN1 | c.2244C>T p.S748= (on ENST00000295591 / NM_001367841.1; = p.S3205= on NM_001164586.2) | Silent (SNP) | VAF 48/427 reads (11%) | catalogued as rs568445190, COSV55170249; called by muse, mutect2, varscan2
